Somatic mutation profile of tumor specimen MP2PRT-PAVKSH-TMP1-A (aliquot MP2PRT-PAVKSH-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVKSH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,304 days).
Specimen MP2PRT-PAVKSH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0828020-6ed4-4864-a011-857e55f1c77c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKSH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKSH-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b70f2694-e854-4563-825e-171cdf27b14d

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.4645C>T p.R1549* | Nonsense Mutation (SNP) | VAF 134/294 reads (46%) | catalogued as rs199679165, CM073411, COSV56339421; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC005324.2 | c.1266G>C p.Q422H | Missense Mutation (SNP) | VAF 71/498 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as rs780543466; called by muse, mutect2, varscan2
- CELF4 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs769180157, COSV58452460; called by muse, mutect2, varscan2
- CTNNA3 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 122/311 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs1234352433; called by muse, mutect2, varscan2
- CYP27A1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 187/443 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370868184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX35 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367968414; called by muse, mutect2, varscan2
- MAN2C1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 121/355 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs748518057; called by muse, mutect2, varscan2
- TEKT4 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 239/554 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782809778; called by muse, mutect2, varscan2
- CYP17A1 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FGD6 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 139/357 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- GPR62 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 215/602 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KMT2A | c.9283_9288delinsGGCCGGGG p.P3095Gfs*5 | Frame Shift Ins (INS) | VAF 172/540 reads (32%) | called by pindel, varscan2*
- RAB33A | c.479A>C p.Q160P | Missense Mutation (SNP) | VAF 226/560 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CFAP44 | c.4908C>T p.S1636= | Silent (SNP) | VAF 144/356 reads (40%) | catalogued as rs766068279; called by muse, mutect2, varscan2
- COL19A1 | c.2766A>G p.S922= | Silent (SNP) | VAF 14/395 reads (4%) | catalogued as rs1157856484; called by muse, mutect2
- GABRA5 | c.240C>T p.Y80= | Silent (SNP) | VAF 156/429 reads (36%) | catalogued as rs755181370, COSV100165971; called by muse, mutect2, varscan2
- PCSK6 | c.1859-14991del | Intron (DEL) | VAF 145/422 reads (34%) | called by mutect2, pindel, varscan2
- ZNF816 | c.190+18C>A | Intron (SNP) | VAF 146/425 reads (34%) | catalogued as COSV54412886; called by muse, mutect2, varscan2
